Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A3F2, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A3F2-06A (Metastatic).

[page 1 of 2]
DEPARTMENT OF
PATHOLOGY

SURGICAL PATHOLOGY REPORT

Procedures/Addenda Attached

Patient: [REDACTED]
MR #: [REDACTED]
DOB/Age/Sex: [REDACTED] Age: M
YNHH Visit #: [REDACTED]
Submitting Physician: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Accessioned: [REDACTED]
Adm-Disch Date: [REDACTED]
Reported: [REDACTED]

Clinical History and Impression:
Metastatic melanoma, left upper back
● year old male
Check for BRAF mutation

Specimen(s) Received:
MELANOMA LEFT UPPER BACK

FINAL DIAGNOSIS

SKIN AND SOFT TISSUE, LEFT UPPER BACK, EXCISION:

- MALIGNANT MELANOMA (SEE NOTE)

NOTE: The lesion is identified in the subcutaneous tissue and deep dermis. An intraepidermal component is not seen. This pattern is compatible with metastatic or recurrent melanoma. As requested, the specimen was submitted for BRAF mutation testing, which will be reported separately.

Pathologist:

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received fresh labeled with the patient's name and "melanoma, left upper back, stitch at 12 o'clock, orange dye marks wedge x 2, sent to Dr. [REDACTED] is an irregularly shaped portion of tan-pink hair-bearing skin which measures 9.8 x 9.5 cm and is excised to a maximum depth of 2.7 cm. The specimen is oriented via a single suture designated as 12 o'clock as per the container and requisition sheet. There are two previously made, probable surgical defects located at 3 o'clock and 6 o'clock. Also present are two superficial defects over-inked with orange dye representing areas sent to Dr. [REDACTED] for research. The surgical defects are reapproximated and the deep margin is inked as follows: from 12 o'clock to 3 o'clock to 6 o'clock is blue, from 6 o'clock to 9 o'clock to 12 o'clock is black. The specimen is serially sectioned from 12 o'clock to 6 o'clock to reveal 6 distinct tan-black to tan-brown, well-defined lobulated lesions ranging in size from 3.4 cm to 0.4 cm in greatest dimension. One of these lesions is raised and involves the surface of the skin. Gross photographs of the specimen are taken. Representative sections are submitted in five cassettes.

Page 1 of 2

ICA-0-3
Melanoma NOS 8720/3
Site: soft tissue, back C49.6

lw
11/13/11

ICD-9 Discrepancy		X
Prior Malignant History		X
Duct/Syncytium as Primary		X
Case is (Initial)	C12M1P1 / DISQUALIFIED	

[page 2 of 2]
Summary of Tissue Submitted for Microscopic Examination

Part 1) MELANOMA LEFT UPPER BACK

Block Detail

# Blocks	Designation	#	Description
5	[Undes]	(5)	(No Description)

Procedures/Addenda

MOLECULAR DIAGNOSTIC TESTS

Status: Signed Out 5/1/09

Pathologist:

Ordered:

Reported

Findings (Results)

PCR-SSCP analysis of BRAF gene was performed on [redacted]

BRAF gene V600E mutation was IS NOT identified.

Analytic specific reagent (ASR) is used. This test was developed and its performance characteristics determined by the [redacted]. The test has not been cleared or approved by the U.S. Food and Drug Administration. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Interpretation

The BRAF gene encodes a protein that is a component of the RAS/MAPK signaling pathway involving the control of cell proliferation, differentiation, and apoptosis. This gene may be mutated in many types of cancer, particularly thyroid cancer. BRAF mutation (V600E) occurs in 40-60% of papillary thyroid cancer (PTC). It has been shown that such mutations are associated with a more aggressive phenotype of PTC. BRAF mutation testing of FNA specimens provides a powerful tool to preoperatively identify PTC patients at higher risk for extensive disease (extrathyroidal extension and lymph node metastases). Journal of Clinical Oncology 27:2977-2982, 2009.

BRAF V600E mutation is not detected in the specimen tested.

Testing was performed by the [redacted]

Source: NCI Genomic Data Commons file f34873be-a260-4a73-ba5f-d126c90a34db (TCGA-DA-A3F2.557E3055-9BFB-4849-AD98-E6D6510FAA42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).